Surgical pathology report (de-identified scan), TCGA case TCGA-SR-A6MX, project TCGA-PCPG (Pheochromocytoma and Paraganglioma), tissue source site Tufts Medical Center, specimen TCGA-SR-A6MX-01A (Primary Tumor).

[page 1 of 2]
Specimen:

Procedure:

Accessioned:

Reported:

Submitting Phys:

Patient:

Medical Record #:

DOB/Age/Sex:

Location/Client:

Account #:

(Age:) M

Surgical Pathology Report

Final Diagnosis

A, B) EPIDURAL MASS, RESECTION:

- PARAGANGLIOMA, WITH FOCAL COAGULATIVE NECROSIS CONSISTENT WITH RECENT ISCHEMIA.
- MITOSES ARE NOT IDENTIFIED.
- TUMOR EXTENDS TO RESECTION MARGINS.

C) SCALP TUMOR, RESECTION:

- PARAGANGLIOMA (6 CM GREATEST DIMENSION), METASTATIC TO SKULL.
- TUMOR EXTENSIVELY INVOLVES THE BONE OF THE SKULL AND INVADERS THROUGH THE BONE BOTH EXTERNALLY AND INTERNALLY. THE OVERLYING SKELETAL MUSCLE AND ADIPOSE TISSUE OF THE SCALP IS DISTENDED BY A PUSHING BORDER OF TUMOR, BUT ONLY FOCALLY INVADDED.
- LYMPHOVASCULAR INVASION IS PROMINENT (SLIDE C12).
- THERE IS EXTENSIVE TUMOR NECROSIS.
- MITOSES ARE VARIABLY PRESENT (UP TO 3 PER HIGH POWER FIELD IN SOME FOCI) BUT ARE RARE OVERALL.
- Ki-67 LABELING IS APPROXIMATELY 10% IN AREAS OF HIGHEST LABELING.
- TUMOR EXTENDS TO BONE AND SOFT TISSUE MARGIN AT THE SHORT AXIS OF THE BONE EXCISION (BEST SEEN IN C12).
- IMMUNOHISTOCHEMICAL STAINING FOR SDHB IS NEGATIVE IN TUMOR CELLS AND POSITIVE IN ENDOTHELIAL CELLS, CONSISTENT WITH A SDHx GENE MUTATION.
- IMMUNOHISTOCHEMICAL STAINS FOR CHROMOGRANIN A AND TYROSINE HYDROXYLASE ARE DIFFUSELY POSITIVE.

Comments

All controls show appropriate reactivity.

*ICD-O-3
Paraganglioma, malignant 8680/3
Site: Epidural C72.9
JW 7/15/13*

***Report Electronically Signed By

This certifies that the pathologist named above has personally conducted a microscopic examination (or gross examination only, where stated) of the described specimen(s) and has rendered or confirmed the final diagnosis(es).

Intra-Operative Consultation with Frozen Section

AFS) EPIDURAL MASS:

- PARAGANGLIOMA.

Clinical History

T2-3 epidural mass.

[page 2 of 2]
Pre-Operative Diagnosis
(Not Provided)

Post-Operative Diagnosis
(Not Provided)

Gross Description

A. T2-3 EPIDURAL MASS (FRESH) The specimen, labeled with the patient's name _____ and medical record number, is a fragment of dark red to brown soft tissue (2.5 x 1.5 x 0.2 cm). The specimen is processed for intraoperative frozen section diagnosis and entirely submitted in cassettes A1-2 (A1 = frozen section remnant).

B. EPIDURAL TUMOR (#2 ADDITIONAL PIECE OF TUMOR) (FRESH): The specimen, labeled with the patient's name _____ and medical record number, consists of multiple fragments of red to brown soft tissue (0.5 x 0.4 x 0.4 cm). The specimen is entirely submitted in cassette B1.

C. SCALP TUMOR (FRESH): The specimen, labeled with the patient's name _____ and medical record number, consists of an ovoid soft tissue mass (6 x 5 x 2 cm) attached to an ovoid fragment of skull (5.6 x 4 x 0.4 cm). The cut surface reveals a well circumscribed tan-pink mass distending but not invading the overlying fibrous tissue and skeletal muscle (6 x 4.5 x 2 cm). The mass penetrates through the bone at the mid portion of the specimen, closest to the resection margins along the short axis. Resection margins along the long axis appear to be free of tumor. The specimen is serially sectioned along the short axis and entirely submitted consecutively from cassettes C1-17. The cut surface of the mass is pink-tan with patchy yellow areas of necrosis. Approximately 20% of the tumor appears necrotic.

Immunohistochemical staining performed in this case may involve reagents labeled as analyte specific reagents. For these cases: This test was developed and its performance characteristics determined by _____ It has not been cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. This test is used for clinical purposes. It should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical laboratory testing.

*Skull met is being submitted
with this primary. BCE*

Department of Pathology
- End of Report -

Page 2 of 2
Printed:

Four Malignancy History	☒	☒

Source: NCI Genomic Data Commons file 81d233b3-34ca-4019-93f6-997e47ce2dd2 (TCGA-SR-A6MX.8CEC34C5-FEDE-4E82-B492-9B4230A04DE0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).